Surgical pathology report (de-identified scan), TCGA case TCGA-06-2565, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-2565-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Surgical Pathology Report

TCGA-06-2565

=====

CLINICAL HISTORY

[REDACTED] has had severe headache for about two weeks. [REDACTED] and on the MRI there were findings consistent with a stroke. On current studies there are three enhancing lesions, largest one in left temporoparietal area.

OPERATIVE DIAGNOSES

Left parietal mass lesion

Operation/Specimen: A: Brain, left parietal tumor, biopsy
; Brain, excisional biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, left parietal, excisional biopsies:

1. Glioblastoma.
2. MIB-1 proliferation index: 35%.
- See Microscopy Description and Comment.

COMMENT

The neoplasm is a very cellular glial neoplastic proliferation of mostly naked nuclei with irregular contours. The neoplasm has brisk mitotic activity and a high proliferation index of about 35%. The tumor has focal microvascular cellular proliferation and tumor necrosis. Focally there is an arciform capillary-type vascular network and very sparse microcalcification.

The neoplasm has histological features of glioblastoma. Molecular testing to rule out the possibility of an oligodendroglial component is being performed, and the result will be reported as an addendum.

[REDACTED]

=====

PROCEDURES/ADDENDA

ss of Heterozygosity by 19q Assay (LOH)

[REDACTED]

Interpretation

[REDACTED]

[page 2 of 3]
[REDACTED]

[REDACTED]

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tumor paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A.
Brain, left parietal tumor, biopsy, touch prep and smears: Glioma, high histological grade (C/W glioblastoma). [REDACTED] Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

[page 3 of 3]
GROSS DESCRIPTION

A.
"Left parietal," received fresh, five fragments, 1.0 cm. in aggregate. Semi firm, glassy, greyish-pink. In total, A1 to A3.

B.
SPECIMEN: Left parietal tumor
FIXATIVE: None
GENERAL: Irregular red tan to red gray fragments of brain tissue ranging from 0.3-0.9 cm in greatest dimension. Fragments have combined weight of 0.47 gm.
SECTIONS: B1-all submitted

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates gliofibrillogenesis by the neoplastic cells. A large proportion of neoplastic cells over express the p53 protein. With the MIB-1 there is a proliferation index of about 35% throughout the tumor.

ICD-9(s):
191.9 191.9

Isto Data

Part A: Brain, left parietal tumor biopsy

Taken:

Stain/cnt	Block	Ordered	Comment
CD163 Vector x 1	1		
EGFR-curls x 1	1		
mGFAP-DA x 1	1		
H/E x 1	1		
MGMT-curls x 1	1		Please do 1p,19q LOH also.
Thanks.			
MIB1-DA x 1	1		
P53DO7 x 1	1		
TPS H/E x 1	1		
H/E x 1	2		
H/E x 1	3		

Part B: Brain, excisional biopsy

Taken:

Received:

Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
H/E x 1	2		
H/E x 1	3		

*** End of Report ***

Source: NCI Genomic Data Commons file 8b3be405-bb3c-41bc-bd46-974b63dea282 (TCGA-06-2565.2888B563-470D-4600-AB7D-F6B86BD11F7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).